Somatic mutation profile of tumor specimen C3L-06025-03 (aliquot CPT0361880009) from CPTAC case C3L-06025, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.5 years (26,130 days).
Specimen C3L-06025-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63541d55-c086-4ea9-9675-1db507320303.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06025-31 (Blood Derived Normal), aliquot CPT0361960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97b3a5c0-89a4-4130-ae1f-be1747ad8f0c

The open-access MAF lists 423 somatic variants for this specimen: 259 protein-altering or splice-affecting, 155 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 155, Nonsense Mutation 15, Intron 5, Splice Region 4, Frame Shift Del 2, Splice Site 2, 5'Flank 2, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 181/369 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TRAF7 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 115/456 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1268399486, COSV58216723; called by muse, mutect2, varscan2
- ABCA13 | c.9397C>T p.P3133S | Missense Mutation (SNP) | VAF 108/464 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs1307532783, COSV71285034; called by muse, mutect2, varscan2
- ABCA6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs781249897, COSV52638284; called by muse, mutect2, varscan2
- ABCB1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945144; called by muse, mutect2, varscan2
- AC134980.2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 56/185 reads (30%) | catalogued as COSV60906906; called by muse, mutect2, varscan2
- AC136428.1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs761559611; called by muse, varscan2
- ACSM2A | c.985C>T p.P329S (on ENST00000219054; = p.P250S on NM_001308169.2) | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs1372295805, COSV54588761; called by muse, mutect2, varscan2
- ADAMTS5 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs769893123; called by muse, mutect2, varscan2
- ADAMTS6 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV66856785; called by muse, mutect2, varscan2
- ADD2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 92/398 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV52463726; called by muse, mutect2, varscan2
- AGBL1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as rs1277061532; called by muse, mutect2, varscan2
- ALAS2 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as HM080094, COSV58191821; called by muse, mutect2, varscan2
- AMER3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 99/449 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs1365927046; called by muse, mutect2, varscan2
- ARID1B | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1369594791, COSV51662864; called by muse, mutect2, varscan2
- BMP1 | c.2581G>C p.G861R | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60529372; called by muse, mutect2, varscan2
- BMPER | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV51832711; called by muse, mutect2, varscan2
- C6 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV99667135; called by muse, mutect2, varscan2
- CALB2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100226461, COSV56940629; called by muse, mutect2, varscan2
- CALCR | c.1285T>C p.W429R (on ENST00000649521 / NM_001164737.2; = p.W413R on NM_001742.4) | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100810833, COSV64010129; called by muse, mutect2, varscan2
- CASR | c.2854G>A p.E952K (on ENST00000490131; = p.E1029K on NM_000388.4) | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV56141462; called by muse, mutect2, varscan2
- CCDC158 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as rs747436981, COSV66356821; called by muse, mutect2, varscan2
- CCDC40 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 67/438 reads (15%) | catalogued as COSV53901611; called by muse, mutect2, varscan2
- CD200R1L | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV68004254; called by muse, mutect2, varscan2
- CD300LF | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 40/332 reads (12%) | catalogued as rs1291548841; called by muse, mutect2, varscan2
- CD33 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 126/418 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV51803049; called by muse, mutect2, varscan2
- CHRNB3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1162798881, COSV51497466; called by muse, mutect2, varscan2
- CLIP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs531429654; called by muse, mutect2, varscan2
- CNGB3 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs759584325; called by muse, mutect2, varscan2
- CNTNAP2 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); catalogued as COSV62179159; called by muse, mutect2, varscan2
- CNTNAP4 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56695021; called by muse, mutect2, varscan2
- COL4A5 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606309; called by muse, mutect2, varscan2
- COL8A1 | c.329-1G>A p.X110_splice | Splice Site (SNP) | VAF 25/210 reads (12%) | catalogued as COSV53742292; called by muse, mutect2, varscan2
- CPXM2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747279699, COSV53860636; called by muse, mutect2, varscan2
- CRYBB3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369309849; called by muse, mutect2, varscan2
- CRYGD | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs543971587, CM160725; called by muse, mutect2, varscan2
- CSMD1 | c.8849G>A p.G2950E (on ENST00000520002; = p.G2949E on NM_033225.6) | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59372856; called by muse, mutect2, varscan2
- CTNNA2 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs762005209; called by muse, mutect2, varscan2
- CYLC1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV61413401; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- DHCR7 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565893436, CM010205, COSV62794728; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.10658C>T p.S3553F | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54508611, COSV54555645; called by muse, mutect2, varscan2
- DNAH3 | c.9142C>T p.P3048S | Missense Mutation (SNP) | VAF 108/416 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV54541169; called by muse, mutect2, varscan2
- DNAH5 | c.9605G>A p.R3202K | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV99451580; called by muse, mutect2, varscan2
- DNAH8 | c.8191C>T p.P2731S | Missense Mutation (SNP) | VAF 125/401 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs980617815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK9 | c.2341C>T p.P781S (on ENST00000376460 / NM_001366676.2; = p.P782S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1165611272; called by muse, mutect2, varscan2
- ELMO1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1296323394, COSV60323788; called by muse, mutect2, varscan2
- EP400 | c.4012G>A p.V1338I | Missense Mutation (SNP) | VAF 115/395 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs555342070, COSV57768889; called by muse, mutect2, varscan2
- ERBIN | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 45/263 reads (17%) | catalogued as COSV52325071; called by muse, mutect2
- FAM160A1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 144/491 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1228196193; called by muse, mutect2, varscan2
- FAM71D | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs529974050; called by muse, mutect2, varscan2
- FBXO47 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs778288328; called by muse, mutect2, varscan2
- FGL2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs763301081; called by muse, mutect2, varscan2
- GABRG1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.689); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GIPR | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs762840878; called by muse, mutect2, varscan2
- GLI2 | c.2515G>A p.D839N (on ENST00000361492 / NM_001374353.1; = p.D856N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/559 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58042081; called by muse, mutect2, varscan2
- GLYATL3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 134/506 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.59); catalogued as rs1207628346; called by muse, varscan2
- GPR149 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67667786; called by muse, mutect2, varscan2
- GPR174 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52133612, COSV99338087; called by muse, mutect2, varscan2
- GPRC5B | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 119/477 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs757869983, COSV56026278, COSV56026481; called by muse, mutect2, varscan2
- HCFC1 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs782244386; called by muse, varscan2
- HERC2 | c.8284C>G p.R2762G | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs543946257, COSV55321586; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, mutect2, varscan2
- KCNH3 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 126/460 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1215473198; called by muse, varscan2
- KDM6B | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as rs772320061, COSV54681109, COSV99642514; called by muse, mutect2, varscan2
- KRT24 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52880687; called by muse, mutect2, varscan2
- KRT34 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 84/639 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs200888573, COSV101222663, COSV67449953; called by muse, mutect2, varscan2
- LAMP5 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV55718025, COSV55718171; called by muse, mutect2, varscan2
- LCP1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376055074; called by muse, mutect2, varscan2
- LGALS16 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs770163155; called by muse, mutect2, varscan2
- LOXHD1 | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196645388; called by muse, mutect2, varscan2
- LRCH2 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57762455; called by muse, mutect2, varscan2
- LSM12 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.684); catalogued as rs228753; called by muse, varscan2
- MAGEA10 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV99726814; called by muse, mutect2, varscan2
- MTMR8 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs771959682; called by muse, mutect2, varscan2
- MUC16 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1195093649; called by muse, mutect2, varscan2
- MUC4 | c.11279C>T p.P3760L | Missense Mutation (SNP) | VAF 176/1139 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs1200135698; called by muse, mutect2
- MYH1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56855015; called by muse, mutect2, varscan2
- MYH2 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99820214; called by muse, mutect2, varscan2
- MYH7 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62522063; called by muse, mutect2, varscan2
- NCR3 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53001202; called by muse, mutect2, varscan2
- NELL2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs769425547, COSV100418344, COSV100420210, COSV61576556; called by muse, mutect2, varscan2
- NLRP11 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs141366900; called by muse, mutect2, varscan2
- OBSCN | c.13678G>A p.E4560K | Missense Mutation (SNP) | VAF 162/747 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478288; called by muse, mutect2
- OR13C5 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866884938, COSV101053045, COSV66164263; called by muse, mutect2, varscan2
- OR2H1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 177/708 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1376282042, COSV65810257; called by muse, mutect2, varscan2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, mutect2, varscan2
- OR4A15 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as rs753415282, COSV100124011, COSV59033532; called by muse, mutect2, varscan2
- OR4A16 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as COSV59041753, COSV59043563; called by muse, mutect2, varscan2
- OTOL1 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005900; called by muse, mutect2, varscan2
- PAX5 | c.1085A>G p.N362S | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV63909204; called by muse, mutect2, varscan2
- PCDHB3 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 195/725 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564152; called by muse, varscan2
- PCDHGA1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 110/566 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65294825, COSV65298907; called by muse, mutect2, varscan2
- PCDHGA12 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 92/379 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); catalogued as rs999687684, COSV52749440; called by muse, mutect2, varscan2
- PCDHGA2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 111/438 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV104390612; called by muse, mutect2, varscan2
- PDE7B | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1188639692; called by muse, mutect2, varscan2
- PIPOX | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100037920; called by muse, mutect2, varscan2
- PRAMEF4 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV99339721; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 124/408 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PTPRG | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs563123759, COSV55646756; called by muse, mutect2, varscan2
- PTPRT | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61986686; called by muse, mutect2, varscan2
- PTPRT | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61968759; called by muse, mutect2, varscan2
- PUS10 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as COSV100369426; called by muse, mutect2, varscan2
- RANBP17 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 107/360 reads (30%) | catalogued as rs200104921; called by muse, mutect2, varscan2
- RICTOR | c.4402C>G p.L1468V | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV57130969; called by muse, mutect2, varscan2
- RINT1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs765492463, COSV57559745, COSV57560690; called by muse, mutect2, varscan2
- RNF213 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs1296922526; called by muse, mutect2, varscan2
- RTN1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 124/503 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV50719166; called by muse, mutect2, varscan2
- SALL4 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53852269; called by muse, mutect2, varscan2
- SCARB2 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53668825; called by muse, mutect2, varscan2
- SCN2B | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV54050396; called by muse, mutect2, varscan2
- SDK1 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67387075; called by muse, mutect2, varscan2
- SERPINC1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 187/606 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as CM113644, COSV62928951; called by muse, mutect2, varscan2
- SERPINE3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68545158; called by muse, mutect2, varscan2
- SH3GL3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs373378258; called by muse, mutect2, varscan2
- SH3TC1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 185/663 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as rs1389451510; called by muse, mutect2, varscan2
- SIX3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs768427864; called by muse, mutect2, varscan2
- SMCR8 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 62/222 reads (28%) | catalogued as COSV58177078; called by muse, mutect2, varscan2
- SOWAHD | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs764308223; called by muse, mutect2, varscan2
- TBC1D32 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 71/281 reads (25%) | catalogued as COSV99249832; called by muse, mutect2, varscan2
- TECRL | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101168904; called by muse, mutect2, varscan2
- TGS1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52697939; called by muse, mutect2, varscan2
- TMEM200A | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1190605723, COSV51649875; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 52/447 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as rs555154458, COSV64101333; called by muse, mutect2, varscan2
- TRAV1-2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs570423010; called by muse, varscan2
- TSG101 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV52652287; called by muse, mutect2, varscan2
- TSSK4 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 116/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1477796743; called by muse, mutect2, varscan2
- UCP2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs267603185; called by muse, mutect2, varscan2
- UGT2B15 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57733812; called by muse, mutect2, varscan2
- UGT8 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV60417280; called by muse, mutect2, varscan2
- UQCC1 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 81/316 reads (26%) | catalogued as COSV62903185; called by muse, mutect2, varscan2
- UROC1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52036957; called by muse, mutect2, varscan2
- WNK3 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV63613298; called by muse, mutect2, varscan2
- WSCD2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54578672, COSV54582968; called by muse, mutect2, varscan2
- XAF1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as rs1337793814; called by muse, mutect2, varscan2
- ZDBF2 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV65622169, COSV65625388; called by muse, mutect2, varscan2
- ZFP14 | c.1285T>G p.C429G | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54202177; called by muse, mutect2, varscan2
- ZMIZ2 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 147/600 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs745533658; called by muse, mutect2, varscan2
- ZNF180 | c.167T>A p.V56D | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55422142; called by muse, mutect2, varscan2
- ZNF653 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs749047210, COSV53402281; called by muse, mutect2, varscan2
- ZNF675 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated, low confidence (1); catalogued as rs958459883; called by muse, mutect2, varscan2
- ZNF700 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.882); catalogued as rs1193915848; called by muse, mutect2, varscan2
- ZNF80 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57362934; called by muse, mutect2, varscan2
- AC007040.2 | c.431_434delinsCTT p.L144Pfs*19 | Frame Shift Del (DEL) | VAF 60/419 reads (14%) | called by pindel, varscan2*
- ACSBG2 | c.1089G>A p.G363= | Splice Region (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- ACTL7A | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTR5 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGPAT4 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 72/240 reads (30%) | called by muse, mutect2, varscan2
- AHNAK2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- AICDA | c.435T>A p.F145L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); called by muse, varscan2
- AJM1 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD26 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARSI | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 126/522 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.2342T>C p.V781A | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- C10orf88 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C4orf50 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CACNA1A | c.4520A>T p.N1507I | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARD10 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 136/346 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD11 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CC2D2A | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CC2D2A | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CCDC168 | c.7981C>T p.P2661S | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CCDC88B | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM3 | c.1519T>G p.Y507D | Missense Mutation (SNP) | VAF 168/458 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CLSTN2 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, varscan2
- CPN2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYZ | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 110/214 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CSNK1E | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DHX29 | c.2688A>T p.E896D | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.4606C>T p.Q1536* | Nonsense Mutation (SNP) | VAF 138/542 reads (25%) | called by muse, mutect2, varscan2
- DMTN | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- DNAH11 | c.7445T>C p.V2482A | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH9 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH9 | c.8003C>T p.P2668L | Missense Mutation (SNP) | VAF 124/376 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK3 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ELFN2 | c.1949A>T p.H650L | Missense Mutation (SNP) | VAF 175/510 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPL1 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 91/407 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EXO1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 84/365 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FCRL6 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLNA | c.7307G>A p.G2436E (on ENST00000369850 / NM_001110556.2; = p.G2428E on NM_001456.3) | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNA | c.4976G>A p.G1659D (on ENST00000369850 / NM_001110556.2; = p.G1651D on NM_001456.3) | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FRAS1 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- GAPDHS | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- GBA3 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 83/343 reads (24%) | called by muse, mutect2, varscan2
- GLIPR1L1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GNPTAB | c.2834A>G p.K945R | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- HLCS | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IFT80 | c.1768del p.A590Lfs*7 | Frame Shift Del (DEL) | VAF 98/290 reads (34%) | called by mutect2, pindel*, varscan2
- IGFL3 | c.351G>A p.R117= | Splice Region (SNP) | VAF 69/221 reads (31%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- IKZF2 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- IL36G | c.6A>T p.R2S | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC8A | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- KLKB1 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- KMT2D | c.6569C>T p.P2190L | Missense Mutation (SNP) | VAF 159/603 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAS1L | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MAGEE1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEST | c.576G>A p.K192= | Splice Region (SNP) | VAF 105/346 reads (30%) | called by muse, mutect2, varscan2
- MOXD1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTHFD2L | c.914G>A p.G305E (on ENST00000395759 / NM_001144978.2; = p.G247E on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.31705G>A p.A10569T | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC16 | c.17085G>T p.Q5695H | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.4646C>T p.P1549L | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2
- MYO1B | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 109/418 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYT1L | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF14 | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 26/551 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2
- NT5M | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NUP35 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13C9 | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2L3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 166/488 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, varscan2
- OTOA | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKIG | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 130/441 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLB1 | c.3955G>A p.V1319I | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PLD3 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- PPP1R3A | c.3238C>T p.L1080F | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PPP6C | c.648dup p.G217Wfs*7 | Frame Shift Ins (INS) | VAF 62/248 reads (25%) | called by mutect2, pindel, varscan2
- PRG4 | c.3512G>A p.W1171* | Nonsense Mutation (SNP) | VAF 107/279 reads (38%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRR30 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 116/469 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS16 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PSD3 | c.2515G>A p.E839K (on ENST00000440756; = p.E838K on NM_015310.4) | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PTPDC1 | c.1426C>T p.H476Y (on ENST00000375360 / NM_177995.3; = p.H528Y on NM_152422.4) | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PTPRM | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PWWP3B | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RASIP1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 61/436 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- RICTOR | c.4401T>G p.G1467= | Splice Region (SNP) | VAF 62/208 reads (30%) | called by muse, mutect2, varscan2
- RLIM | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNASEK | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF4 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- SCN10A | c.4937C>T p.T1646I | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHISA6 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC16A2 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 71/444 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- SLC25A12 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC4A10 | c.1691C>T p.T564I (on ENST00000446997 / NM_001354461.2; = p.T534I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SLC6A1 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SOX4 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPHKAP | c.1261A>C p.S421R | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SPRY3 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 83/492 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRGAP2 | c.2329C>T p.P777S (on ENST00000624873 / NM_001170637.4; = p.P778S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- STAC | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STRC | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TAF1 | c.3496C>T p.R1166* (on ENST00000373790 / NM_138923.4; = p.R1187* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/292 reads (16%) | called by muse, mutect2, varscan2
- TCF20 | c.2734G>A p.G912S | Missense Mutation (SNP) | VAF 62/552 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.232); called by muse, varscan2
- TDP1 | c.1754-1G>C p.X585_splice | Splice Site (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- TEX15 | c.2564C>T p.S855F (on ENST00000256246; = p.S1238F on NM_001350162.2) | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TLE2 | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMCO6 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TMEM199 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIML1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 124/458 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIOBP | c.4952C>G p.P1651R | Missense Mutation (SNP) | VAF 61/534 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTC6 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- UGT2B28 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC80 | c.7871G>A p.R2624K | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF699 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ZNF707 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 347/737 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF750 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 167/480 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ABCC8 | c.931C>T p.L311= | Silent (SNP) | VAF 46/518 reads (9%) | called by muse, mutect2
- ACVR2B | c.546C>T p.S182= | Silent (SNP) | VAF 109/338 reads (32%) | catalogued as rs886058386, COSV61702074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM28 | c.1653C>T p.L551= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as rs975099040; called by muse, mutect2, varscan2
- ADAM28 | c.1677C>T p.T559= | Silent (SNP) | VAF 75/276 reads (27%) | called by muse, mutect2
- ADAMTS5 | c.93C>T p.A31= | Silent (SNP) | VAF 64/432 reads (15%) | catalogued as rs748300980; called by muse, mutect2, varscan2
- ADAMTS9 | c.5427G>A p.R1809= | Silent (SNP) | VAF 97/343 reads (28%) | called by muse, mutect2, varscan2
- ADH1B | c.423C>T p.F141= | Silent (SNP) | VAF 112/462 reads (24%) | catalogued as rs372727625; called by muse, mutect2, varscan2
- ALPK3 | c.3951C>T p.G1317= | Silent (SNP) | VAF 53/330 reads (16%) | catalogued as rs934215303, COSV99360910; called by muse, mutect2
- ANKFN1 | c.654C>T p.V218= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as COSV59460568; called by muse, mutect2, varscan2
- ANKRD36 | c.1902T>C p.I634= | Silent (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2, varscan2
- ARAP2 | c.1965G>A p.R655= | Silent (SNP) | VAF 62/202 reads (31%) | called by muse, mutect2, varscan2
- ARSI | c.1425G>A p.E475= | Silent (SNP) | VAF 125/529 reads (24%) | called by muse, mutect2, varscan2
- ATG14 | c.585A>T p.R195= | Silent (SNP) | VAF 93/411 reads (23%) | called by muse, mutect2, varscan2
- ATP7B | c.945C>T p.I315= | Silent (SNP) | VAF 102/373 reads (27%) | catalogued as rs776855440, COSV54435505; called by muse, mutect2, varscan2
- BHLHE41 | c.1320C>T p.P440= | Silent (SNP) | VAF 127/460 reads (28%) | called by muse, mutect2, varscan2
- BPIFB1 | c.210C>T p.I70= | Silent (SNP) | VAF 107/390 reads (27%) | called by muse, mutect2, varscan2
- BRINP2 | c.2298C>T p.F766= | Silent (SNP) | VAF 85/370 reads (23%) | catalogued as rs1246987987; called by muse, mutect2, varscan2
- C1orf94 | c.807C>T p.F269= (on ENST00000488417 / NM_001134734.2; = p.F79= on NM_032884.5) | Silent (SNP) | VAF 177/412 reads (43%) | catalogued as COSV64915398; called by muse, mutect2, varscan2
- CA13 | c.63C>T p.F21= | Silent (SNP) | VAF 125/287 reads (44%) | catalogued as rs1376005776; called by muse, mutect2, varscan2
- CACNA1S | c.699C>T p.I233= | Silent (SNP) | VAF 60/296 reads (20%) | catalogued as rs756008578; called by muse, mutect2, varscan2
- CARD14 | c.2865G>A p.Q955= | Silent (SNP) | VAF 120/465 reads (26%) | catalogued as rs1187693801; called by muse, mutect2, varscan2
- CCKAR | c.969C>T p.F323= | Silent (SNP) | VAF 112/515 reads (22%) | catalogued as COSV55162009; called by muse, mutect2, varscan2
- CCN3 | c.696C>T p.N232= | Silent (SNP) | VAF 241/497 reads (48%) | called by muse, mutect2, varscan2
- CCNT2 | c.1023T>C p.T341= | Silent (SNP) | VAF 93/355 reads (26%) | called by muse, mutect2, varscan2
- CDH8 | c.1140C>T p.I380= | Silent (SNP) | VAF 122/464 reads (26%) | catalogued as rs760196212, COSV54875667; called by muse, mutect2, varscan2
- CDK5R1 | c.294C>T p.F98= | Silent (SNP) | VAF 130/430 reads (30%) | catalogued as rs1210946698; called by muse, varscan2
- CGA | c.111G>A p.Q37= | Silent (SNP) | VAF 69/326 reads (21%) | called by muse, mutect2, varscan2
- CLCN7 | c.1383C>T p.S461= | Silent (SNP) | VAF 73/338 reads (22%) | catalogued as rs372646820; called by muse, mutect2, varscan2
- CNOT6L | c.453C>T p.T151= (on ENST00000504123 / NM_001286790.2; = p.T146= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/325 reads (24%) | catalogued as rs778201566; called by muse, mutect2, varscan2
- COPS7B | c.303C>T p.I101= | Silent (SNP) | VAF 52/268 reads (19%) | catalogued as rs150742456; called by muse, mutect2, varscan2
- CUX1 | c.2742C>T p.S914= | Silent (SNP) | VAF 137/566 reads (24%) | catalogued as COSV52895678; called by muse, mutect2, varscan2
- CYP4F12 | c.975C>T p.F325= | Silent (SNP) | VAF 57/229 reads (25%) | called by muse, mutect2, varscan2
- DCAF5 | c.138G>A p.K46= | Silent (SNP) | VAF 103/417 reads (25%) | called by muse, mutect2, varscan2
- DHX29 | c.1377T>C p.P459= | Silent (SNP) | VAF 81/291 reads (28%) | called by muse, mutect2, varscan2
- DIDO1 | c.5769C>T p.F1923= | Silent (SNP) | VAF 99/419 reads (24%) | catalogued as COSV56634840; called by muse, mutect2, varscan2
- DMD | c.8700C>T p.V2900= | Silent (SNP) | VAF 73/330 reads (22%) | catalogued as COSV100626183; called by muse, mutect2, varscan2
- DNAH17 | c.13086G>A p.E4362= | Silent (SNP) | VAF 41/312 reads (13%) | catalogued as rs765150307; called by muse, mutect2, varscan2
- DOCK10 | c.1836C>T p.T612= | Silent (SNP) | VAF 38/185 reads (21%) | called by muse, mutect2, varscan2
- DOCK2 | c.5088G>A p.R1696= | Silent (SNP) | VAF 65/330 reads (20%) | catalogued as COSV56953372; called by muse, mutect2, varscan2
- DOCK3 | c.5208C>T p.S1736= | Silent (SNP) | VAF 111/371 reads (30%) | called by muse, mutect2, varscan2
- DSG4 | c.798C>T p.F266= | Silent (SNP) | VAF 65/239 reads (27%) | catalogued as COSV57388130; called by muse, mutect2, varscan2
- EFCAB8 | c.2151G>A p.R717= | Silent (SNP) | VAF 92/355 reads (26%) | catalogued as rs1375566095; called by muse, mutect2, varscan2
- ESPL1 | c.750C>T p.C250= | Silent (SNP) | VAF 93/408 reads (23%) | called by muse, mutect2, varscan2
- FANCE | c.1578C>T p.S526= | Silent (SNP) | VAF 90/326 reads (28%) | called by muse, mutect2, varscan2
- FAT4 | c.6994T>C p.L2332= | Silent (SNP) | VAF 70/269 reads (26%) | called by muse, mutect2, varscan2
- FBN1 | c.4962T>C p.T1654= | Silent (SNP) | VAF 98/228 reads (43%) | catalogued as rs151180372; called by muse, mutect2, varscan2
- FREM1 | c.1749C>T p.V583= | Silent (SNP) | VAF 60/152 reads (39%) | called by muse, mutect2, varscan2
- GNB3 | c.66G>A p.R22= | Silent (SNP) | VAF 86/345 reads (25%) | called by muse, mutect2, varscan2
- GNPAT | c.723C>T p.F241= | Silent (SNP) | VAF 63/286 reads (22%) | catalogued as COSV64153010; called by muse, mutect2, varscan2
- GREB1L | c.987C>T p.H329= | Silent (SNP) | VAF 30/242 reads (12%) | called by muse, mutect2, varscan2
- GRM8 | c.1722C>T p.I574= | Silent (SNP) | VAF 130/537 reads (24%) | called by muse, mutect2, varscan2
- H3C3 | c.339T>C p.I113= | Silent (SNP) | VAF 85/306 reads (28%) | called by muse, mutect2, varscan2
- HDX | c.1089T>C p.N363= | Silent (SNP) | VAF 57/305 reads (19%) | called by muse, mutect2, varscan2
- HECTD4 | c.11535C>T p.I3845= | Silent (SNP) | VAF 98/382 reads (26%) | called by muse, mutect2, varscan2
- HNRNPCL1 | c.291G>A p.V97= | Silent (SNP) | VAF 236/503 reads (47%) | catalogued as rs981909786, COSV58610267; called by muse, mutect2, varscan2
- HYDIN | c.12816C>T p.T4272= | Silent (SNP) | VAF 33/211 reads (16%) | catalogued as rs1277163265; called by muse, mutect2, varscan2
- IFRD1 | c.36C>T p.R12= | Silent (SNP) | VAF 40/448 reads (9%) | called by muse, mutect2
- IL9R | c.787C>T p.L263= | Silent (SNP) | VAF 41/233 reads (18%) | catalogued as rs1385750269; called by muse, mutect2, varscan2
- ILRUN | c.516C>T p.V172= (on ENST00000374023 / NM_024294.4; = p.V106= on NM_022758.6) | Silent (SNP) | VAF 62/234 reads (26%) | called by muse, mutect2, varscan2
- INF2 | c.1410C>T p.A470= | Silent (SNP) | VAF 61/207 reads (29%) | called by muse, mutect2, varscan2
- ITPR1 | c.7752G>A p.L2584= (on ENST00000354582; = p.L2529= on NM_002222.7) | Silent (SNP) | VAF 53/341 reads (16%) | catalogued as COSV56972145; called by muse, mutect2, varscan2
- KAT2A | c.1077C>T p.F359= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV56791489; called by muse, mutect2, varscan2
- KCNK10 | c.336C>T p.F112= | Silent (SNP) | VAF 110/426 reads (26%) | catalogued as COSV56652545; called by muse, mutect2, varscan2
- KDM2A | c.2193C>T p.S731= | Silent (SNP) | VAF 40/340 reads (12%) | called by mutect2, varscan2
- KLHL17 | c.1398C>G p.V466= | Silent (SNP) | VAF 55/374 reads (15%) | catalogued as rs769279486, COSV100498217; called by muse, mutect2, varscan2
- KMO | c.96C>T p.F32= | Silent (SNP) | VAF 99/272 reads (36%) | called by muse, mutect2, varscan2
- KRT34 | c.1080C>T p.I360= | Silent (SNP) | VAF 136/552 reads (25%) | catalogued as rs755328052, COSV101222549; called by muse, varscan2
- KRT34 | c.1077G>A p.L359= | Silent (SNP) | VAF 97/547 reads (18%) | called by muse, varscan2
- KRTAP15-1 | c.303C>T p.G101= | Silent (SNP) | VAF 65/378 reads (17%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.204C>T p.I68= | Silent (SNP) | VAF 50/319 reads (16%) | catalogued as COSV100762006; called by muse, mutect2, varscan2
- LOXHD1 | c.2751G>A p.K917= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as rs940679061; called by muse, mutect2, varscan2
- LOXL2 | c.60C>T p.S20= | Silent (SNP) | VAF 55/357 reads (15%) | catalogued as COSV101207756; called by muse, mutect2, varscan2
- LPA | c.3804C>T p.S1268= | Silent (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- LSR | c.582G>A p.R194= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as rs929877997; called by muse, mutect2, varscan2
- MAGEA11 | c.852C>T p.P284= | Silent (SNP) | VAF 58/381 reads (15%) | called by muse, mutect2, varscan2
- MAGEB2 | c.819C>T p.F273= | Silent (SNP) | VAF 61/391 reads (16%) | catalogued as COSV66780210; called by muse, mutect2, varscan2
- MAP3K5 | c.3942C>T p.T1314= | Silent (SNP) | VAF 71/260 reads (27%) | catalogued as rs371929460, COSV62888663; called by muse, mutect2, varscan2
- MAP7D2 | c.2085C>T p.P695= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- MGAM2 | c.3132G>A p.Q1044= | Silent (SNP) | VAF 142/397 reads (36%) | called by muse, mutect2, varscan2
- MICAL2 | c.4482C>T p.L1494= | Silent (SNP) | VAF 124/341 reads (36%) | called by muse, mutect2, varscan2
- MSLN | c.447G>A p.V149= | Silent (SNP) | VAF 121/418 reads (29%) | catalogued as rs1229053173; called by muse, mutect2, varscan2
- MSRB3 | c.462G>A p.G154= | Silent (SNP) | VAF 114/379 reads (30%) | catalogued as rs770392111; called by muse, mutect2, varscan2
- MTDH | c.1467C>T p.S489= | Silent (SNP) | VAF 43/359 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.31170G>A p.R10390= | Silent (SNP) | VAF 98/358 reads (27%) | catalogued as COSV101197858; called by muse, mutect2, varscan2
- MYO3A | c.921C>T p.I307= | Silent (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- NEU3 | c.1038T>C p.S346= | Silent (SNP) | VAF 121/369 reads (33%) | called by muse, mutect2, varscan2
- NLRP7 | c.847C>T p.L283= | Silent (SNP) | VAF 152/610 reads (25%) | catalogued as rs1339723861; called by muse, mutect2, varscan2
- NLRP7 | c.846C>T p.L282= | Silent (SNP) | VAF 133/570 reads (23%) | catalogued as COSV60173079, COSV60179249; called by muse, varscan2
- NYAP1 | c.1539C>T p.P513= | Silent (SNP) | VAF 134/650 reads (21%) | called by muse, mutect2, varscan2
- OLFM4 | c.468C>T p.F156= | Silent (SNP) | VAF 46/324 reads (14%) | catalogued as rs371456757, COSV54578854; called by muse, mutect2, varscan2
- OR1L4 | c.669C>T p.I223= | Silent (SNP) | VAF 48/435 reads (11%) | catalogued as rs140014211, COSV52341184; called by muse, varscan2
- OR4K3 | c.276C>T p.I92= | Silent (SNP) | VAF 91/1192 reads (8%) | called by muse, mutect2
- OR4N2 | c.255C>T p.F85= | Silent (SNP) | VAF 133/1714 reads (8%) | catalogued as rs139052676, COSV60052198; called by muse, mutect2
- OR5AU1 | c.372C>T p.A124= | Silent (SNP) | VAF 101/419 reads (24%) | catalogued as rs199976094, COSV58615748; called by muse, varscan2
- OR5D18 | c.909C>T p.T303= | Silent (SNP) | VAF 23/234 reads (10%) | catalogued as rs375980221, COSV61736558; called by muse, mutect2, varscan2
- OTUD6A | c.630C>T p.I210= | Silent (SNP) | VAF 60/375 reads (16%) | catalogued as COSV57972686; called by muse, varscan2
- PCDHB3 | c.1176C>T p.F392= | Silent (SNP) | VAF 94/395 reads (24%) | catalogued as COSV50574471; called by muse, mutect2, varscan2
- PCDHGA12 | c.840C>T p.S280= | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- PDE6B | c.1629C>T p.F543= | Silent (SNP) | VAF 78/260 reads (30%) | catalogued as rs1205125431; called by muse, mutect2, varscan2
- PEAR1 | c.2616G>A p.R872= | Silent (SNP) | VAF 142/470 reads (30%) | called by muse, mutect2, varscan2
- PIAS3 | c.1806C>T p.A602= | Silent (SNP) | VAF 205/589 reads (35%) | called by muse, mutect2, varscan2
- PLCG1 | c.3253C>T p.L1085= | Silent (SNP) | VAF 102/334 reads (31%) | called by muse, mutect2, varscan2
- PLEC | c.13095C>T p.S4365= (on ENST00000322810 / NM_201380.4; = p.S4255= on NM_000445.5) | Silent (SNP) | VAF 257/558 reads (46%) | called by muse, mutect2, varscan2
- PLIN1 | c.651C>T p.S217= | Silent (SNP) | VAF 194/508 reads (38%) | catalogued as COSV100261586; called by muse, mutect2, varscan2
- PLIN5 | c.414C>T p.R138= | Silent (SNP) | VAF 60/465 reads (13%) | catalogued as rs1438636661; called by muse, mutect2, varscan2
- POU6F2 | c.366C>T p.L122= | Silent (SNP) | VAF 88/479 reads (18%) | catalogued as rs138654387; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKACA | c.717C>T p.F239= | Silent (SNP) | VAF 86/267 reads (32%) | catalogued as rs752866900; called by muse, mutect2, varscan2
- PRMT5 | c.1242C>T p.T414= | Silent (SNP) | VAF 90/330 reads (27%) | catalogued as rs140323472, COSV104369846; called by muse, mutect2, varscan2
- PRR23A | c.381C>T p.F127= | Silent (SNP) | VAF 89/361 reads (25%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2793C>T p.F931= | Silent (SNP) | VAF 91/391 reads (23%) | catalogued as rs751852823; called by muse, mutect2, varscan2
- RASAL2 | c.447C>T p.A149= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as rs763191586; called by muse, mutect2, varscan2
- RELN | c.7611G>A p.G2537= | Silent (SNP) | VAF 105/413 reads (25%) | catalogued as COSV58999797; called by muse, mutect2, varscan2
- RIMS1 | c.3582G>A p.R1194= | Silent (SNP) | VAF 103/333 reads (31%) | called by muse, mutect2, varscan2
- RNF128 | c.630C>T p.F210= (on ENST00000255499 / NM_194463.2; = p.F184= on NM_024539.3) | Silent (SNP) | VAF 42/245 reads (17%) | catalogued as rs866543939, COSV55249071; called by muse, mutect2, varscan2
- ROBO2 | c.453C>T p.I151= | Silent (SNP) | VAF 46/273 reads (17%) | called by muse, mutect2, varscan2
- RP1L1 | c.2175C>T p.G725= | Silent (SNP) | VAF 141/453 reads (31%) | called by muse, mutect2, varscan2
- RPL29 | c.177C>T p.A59= | Silent (SNP) | VAF 77/304 reads (25%) | catalogued as rs758197947; called by muse, mutect2, varscan2
- RSAD2 | c.973C>T p.L325= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as rs1018217654; called by muse, mutect2, varscan2
- SALL4 | c.1842G>A p.G614= | Silent (SNP) | VAF 92/416 reads (22%) | called by muse, mutect2, varscan2
- SCN5A | c.5001C>T p.V1667= (on ENST00000333535 / NM_198056.3; = p.V1666= on NM_000335.5) | Silent (SNP) | VAF 59/416 reads (14%) | called by muse, mutect2, varscan2
- SF3A2 | c.1092C>T p.V364= | Silent (SNP) | VAF 76/507 reads (15%) | called by muse, mutect2, varscan2
- SH2B2 | c.1455C>T p.F485= | Silent (SNP) | VAF 181/539 reads (34%) | catalogued as rs1554557248; called by muse, mutect2, varscan2
- SIX3 | c.648G>T p.R216= | Silent (SNP) | VAF 89/380 reads (23%) | called by muse, mutect2, varscan2
- SLC35B4 | c.330C>T p.I110= | Silent (SNP) | VAF 46/234 reads (20%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.102G>A p.R34= | Silent (SNP) | VAF 102/427 reads (24%) | catalogued as COSV65809197; called by muse, mutect2, varscan2
- SLFN11 | c.876G>A p.P292= | Silent (SNP) | VAF 73/235 reads (31%) | catalogued as rs138127975; called by muse, mutect2, varscan2
- SPTBN2 | c.6468G>A p.Q2156= | Silent (SNP) | VAF 45/383 reads (12%) | catalogued as COSV59457879; called by muse, mutect2, varscan2
- STAT5A | c.1872C>T p.I624= | Silent (SNP) | VAF 79/280 reads (28%) | catalogued as rs143308879; called by muse, mutect2, varscan2
- STX18 | c.309C>T p.F103= | Silent (SNP) | VAF 98/321 reads (31%) | called by muse, mutect2, varscan2
- SWI5 | c.345C>T p.F115= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs529693581; called by muse, mutect2, varscan2
- SYTL5 | c.1317G>A p.K439= | Silent (SNP) | VAF 38/221 reads (17%) | called by muse, mutect2, varscan2
- TAF11L9 | c.63G>A p.K21= | Silent (SNP) | VAF 25/2543 reads (1%) | called by muse, mutect2
- TG | c.7221C>T p.F2407= | Silent (SNP) | VAF 51/493 reads (10%) | called by muse, mutect2, varscan2
- TNRC18 | c.8232G>A p.G2744= | Silent (SNP) | VAF 120/503 reads (24%) | called by muse, mutect2, varscan2
- TPTE | c.469T>C p.L157= (on ENST00000618007 / NM_199261.4; = p.L139= on NM_199259.4) | Silent (SNP) | VAF 47/330 reads (14%) | called by muse, mutect2, varscan2
- TRIM15 | c.354C>T p.F118= | Silent (SNP) | VAF 155/504 reads (31%) | catalogued as COSV100938783; called by muse, mutect2, varscan2
- TRPM2 | c.1989C>T p.S663= | Silent (SNP) | VAF 108/345 reads (31%) | catalogued as rs747905803, COSV100309282; called by muse, mutect2, varscan2
- TSHZ2 | c.1542G>A p.G514= | Silent (SNP) | VAF 94/430 reads (22%) | catalogued as rs1568837417; called by muse, mutect2, varscan2
- TUBGCP6 | c.1515C>T p.L505= | Silent (SNP) | VAF 150/377 reads (40%) | called by muse, mutect2, varscan2
- TWNK | c.808C>T p.L270= | Silent (SNP) | VAF 106/301 reads (35%) | called by muse, mutect2, varscan2
- UNC5A | c.312C>T p.V104= | Silent (SNP) | VAF 75/309 reads (24%) | catalogued as COSV56170623; called by muse, mutect2, varscan2
- UROC1 | c.549C>T p.P183= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- VIL1 | c.360G>A p.G120= | Silent (SNP) | VAF 39/232 reads (17%) | catalogued as rs765315248, COSV50285682; called by muse, mutect2, varscan2
- WARS1 | c.159C>T p.A53= | Silent (SNP) | VAF 92/325 reads (28%) | called by muse, mutect2, varscan2
- WDFY4 | c.5460C>T p.F1820= | Silent (SNP) | VAF 124/344 reads (36%) | catalogued as COSV55423928; called by muse, mutect2, varscan2
- WDPCP | c.1776C>T p.L592= | Silent (SNP) | VAF 53/245 reads (22%) | catalogued as rs750355059; called by muse, mutect2, varscan2
- WDR19 | c.1461C>T p.F487= | Silent (SNP) | VAF 81/281 reads (29%) | called by muse, mutect2, varscan2
- WDR6 | c.1119C>T p.L373= | Silent (SNP) | VAF 50/374 reads (13%) | catalogued as rs142971978; called by muse, mutect2, varscan2
- XIRP1 | c.711G>A p.T237= | Silent (SNP) | VAF 52/415 reads (13%) | catalogued as rs141262169, COSV100453528; called by muse, mutect2, varscan2
- XKR3 | c.1314G>A p.R438= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as COSV100509333; called by muse, mutect2
- ZBED9 | c.1398C>T p.T466= | Silent (SNP) | VAF 134/523 reads (26%) | catalogued as COSV71729734; called by muse, mutect2
- ZC3H3 | c.876C>T p.A292= | Silent (SNP) | VAF 63/811 reads (8%) | catalogued as rs1195173690; called by muse, mutect2
- ZNF229 | c.1791G>A p.E597= | Silent (SNP) | VAF 115/401 reads (29%) | called by muse, mutect2, varscan2
- ZNF268 | c.1377C>T p.L459= | Silent (SNP) | VAF 108/438 reads (25%) | called by muse, mutect2, varscan2
- ZNF750 | c.1497G>A p.E499= | Silent (SNP) | VAF 165/478 reads (35%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824768 C>T | 5'Flank (SNP) | VAF 33/157 reads (21%) | catalogued as rs766480561; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826660 C>T | 3'Flank (SNP) | VAF 51/243 reads (21%) | catalogued as rs1297881448; called by muse, mutect2, varscan2
- C3orf52 | c.*313C>T | 3'UTR (SNP) | VAF 117/359 reads (33%) | catalogued as rs896654193, COSV53495612; called by muse, mutect2, varscan2
- C4orf50 | chr4:5989914 C>T | 5'Flank (SNP) | VAF 85/338 reads (25%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-11859C>T | Intron (SNP) | VAF 72/211 reads (34%) | called by muse, mutect2, varscan2
- MCRS1 | c.11-205dup | Intron (INS) | VAF 76/377 reads (20%) | called by mutect2, pindel, varscan2
- NSRP1 | c.114+9758C>T | Intron (SNP) | VAF 47/181 reads (26%) | called by muse, mutect2, varscan2
- SSX5 | c.69+164C>T | Intron (SNP) | VAF 38/188 reads (20%) | catalogued as rs782103917; called by muse, mutect2, varscan2
- ZNF208 | c.226+153G>A | Intron (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
